Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5431, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5431-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) CONTENTS OF RIGHT NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 10 RIGHT LEVEL III LYMPH NODES.
Three lymph nodes, no tumor, level II, right side.
Six lymph nodes level IV right side, no tumor present.
Five lymph nodes level V, no tumor present.
- (B) CONTENTS OF LEFT NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN 3 OF 6 LEFT LEVEL II LYMPH NODES.
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 9 LEFT LEVEL III LYMPH NODES.
METASTATIC SQUAMOUS CARCINOMA IN 3 OF 4 LEFT LEVEL IV LYMPH NODES.
Two lymph nodes left level V lymph nodes, no tumor.
- (C) TOTAL LARYNGECTOMY AND PARTIAL PHARYNGECTOMY:
POORLY DIFFERENTIATED NON-KERATINIZING SQUAMOUS CARCINOMA OF RIGHT PYRIFORM SINUS MEASURING 3.5 X 1.5 X 1.3 CM INVOLVING LATERAL WALL OF LARYNX WITHOUT INVASION OF BONE. MARGINS OF RESECTION ARE FREE OF TUMOR.
Vocal scar with edema.
Inflammation and fibrosis, no tumor.
- (D) TEETH:
Teeth (gross diagnosis only).

GROSS DESCRIPTION

- (A) CONTENTS OF RIGHT NECK DISSECTION, LEVEL 2 - A 2.5 x 1.5 x 0.3 cm pink-yellow fragment of adipose tissue. Level 3 (4.0 x 2.0 x 1.0 cm). Level 4 (2.5 x 1.2 x 0.4 cm) and level 5 (8.5 x 2.8 x 0.6 cm).
SECTION CODE: A1, one lymph node from level 2; A2, one lymph node from level 2; A3, one section lymph node from level 2; A4, 1 lymph node from level 3; A5, 5 lymph nodes from level 3; A6, 4 lymph nodes from level 3; A7, 4 lymph nodes from level 4; A8, 3 lymph nodes from level 4; A9, 4 lymph nodes from level 5; A10, 1 lymph node from level 5.
- (B) CONTENTS OF LEFT NECK DISSECTION - Several pink-yellow fragments of adipose tissue with lymph nodes; level 2 (4.5 x 3.2 x 2.2 cm) with several enlarged lymph nodes, the largest of which measures 3.2 cm in greatest dimension and contains metastatic carcinoma; level 3 (4.0 x 3.0 x 2.0 cm) which contains a 3.0 cm grossly positive lymph node as well as additional lymph nodes, levels 4 (4.5 x 3.5 x 2.0 cm) contains three grossly positive lymph nodes, the largest of which measures 2.9 cm in greatest dimension, level 5 (10.0 x 2.0 x 0.6 cm) with several lymph nodes.
SECTION CODE: B1, 1 bisected lymph node from level 2; B2, 3 lymph nodes from level 2; B3, 1 bisected lymph node from level 2; B4, a portion of grossly

[page 2 of 2]
[REDACTED]

positive lymph node from level 2; B5, portion of another grossly positive lymph node from level 2; B6, fragment of grossly positive lymph node from level 3; B7, 5 lymph nodes from level 3; B8, 3 lymph nodes from level 3; B9, fragment of grossly positive lymph node from level 4; B10, fragment of another grossly positive lymph node from level 4; B11, fragment of another grossly positive lymph node from level 4; B12, one lymph node from level 4; B13, 3 lymph nodes from level 5. [REDACTED]

(C) TOTAL LARYNGECTOMY AND PARTIAL PHARYNGECTOMY - A total laryngectomy and partial pharyngectomy with overall measurement of 10.0 x 7.0 x 4.5 cm. A fungating and ulcerated lesion located in the left pyriform sinus measures 3.5 x 1.5 x 1.3 cm is noted. The tumor penetrates the soft tissue but does not destroy the bone. The mucosal surface appears grossly uninvolved. The right and left transglottic cords are unremarkable.

SECTION CODE: C1-C4, tumor; C5, right transglottic cord; C6, left transglottic cord; C7-C19, sequential of mucosa and tumor from left to right. [REDACTED]

*FS/DX: MUCOSAL MARGIN, FREE. [REDACTED]

(D) TIPS - [REDACTED] from 1.5 x 0.4 x 0.3 cm to 2.3 x 0.8 x 0.4 cm. Areas of black discoloration are noted on the tip of the tooth surface. The specimen is for gross only. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cb8bde02-f4b1-476d-b257-2894d3a2c9d3 (TCGA-CV-5431.CCCDB903-4228-41C9-8BD4-0F4AA2D4ABA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).